TCGA case TCGA-24-2261 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eec69ea9-ceb8-456a-aff4-41fb8a261e36

Demographics
Sex at birth: female; Race: white; Age at index: 76 years; Vital status: Dead; Days to death: 24 days.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.4 years (27,897 days); Year of diagnosis: 1992; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 11-20 mm.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 24 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1.4; Shortest dimension: 0.4.
  Slide TCGA-24-2261-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 1; Percent necrosis: 5; Percent stromal cells: 9.
  Slide TCGA-24-2261-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 1; Percent necrosis: 5; Percent stromal cells: 9.
- Sample TCGA-24-2261-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 24 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 24 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 24 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2261-01A-01D-0663-01): tumor purity 0.74, ploidy 2.77, whole-genome doublings 1.
